Somatic mutation profile of tumor specimen TCGA-VP-A87J-01A (aliquot TCGA-VP-A87J-01A-11D-A34U-08) from TCGA case TCGA-VP-A87J, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.9 years (20,792 days).
Specimen TCGA-VP-A87J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8b14809-430e-4dad-8ca0-33bf44622af9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VP-A87J-10A (Blood Derived Normal), aliquot TCGA-VP-A87J-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3b0678b-929b-43b2-b056-046d31e23b39

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 16, Silent 6, Nonsense Mutation 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MED12 | c.3667G>C p.V1223L | Missense Mutation (SNP) | VAF 19/22 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100375878, COSV61346311; called by muse, mutect2, varscan2
- ADAM12 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs374529217, COSV64105363; called by muse, mutect2, varscan2
- ARID1A | c.3913C>T p.P1305S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.253); catalogued as rs1014988053, COSV61389532; called by muse, mutect2, varscan2
- CDKN1B | c.431T>G p.L144* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99963915; called by muse, mutect2
- COLEC12 | c.572A>G p.N191S | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV101232048; called by muse, mutect2
- DNAJC25 | c.953A>G p.N318S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV100543354; called by muse, mutect2, varscan2
- EIF4E | c.61A>C p.K21Q | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.336); catalogued as COSV99794753; called by muse, mutect2, varscan2
- HSPB3 | c.103T>C p.Y35H | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100115918; called by muse, mutect2, varscan2
- IGF2BP1 | c.1219A>G p.M407V | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs574660242, COSV99288583; called by muse, mutect2, varscan2
- LRRC7 | c.1262T>C p.L421S (on ENST00000651989 / NM_001370785.2; = p.L388S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99226220; called by muse, mutect2
- NCKAP1L | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 99/246 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1265995510, COSV53211580; called by muse, mutect2, varscan2
- NLRP7 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.511); catalogued as COSV60174420; called by muse, mutect2, varscan2
- PSG1 | c.1209G>T p.K403N | Missense Mutation (SNP) | VAF 103/288 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.284); catalogued as COSV99739734; called by muse, mutect2, varscan2
- TTN | c.45746A>C p.E15249A (on ENST00000591111; = p.E7825A on NM_003319.4) | Missense Mutation (SNP) | VAF 56/137 reads (41%) | PolyPhen probably damaging (0.995); catalogued as rs752204728, COSV100608914; ClinVar: benign / uncertain significance / likely benign; called by muse, mutect2, varscan2
- USP10 | c.1424T>C p.M475T | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs764185302, COSV99551337; called by muse, mutect2, varscan2
- UTP14C | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.2); catalogued as COSV73000723; called by muse, mutect2
- ZFAT | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as rs1294451941, COSV64739318; called by muse, mutect2, varscan2
- ZNF45 | c.1187G>C p.G396A | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as rs770645722, COSV99524112; called by muse, mutect2, varscan2
- GPC2 | c.80_81insCAA p.A26_K27insN | In Frame Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- CNTROB | c.93G>T p.S31= | Silent (SNP) | VAF 50/141 reads (35%) | catalogued as rs759944922, COSV100366443; called by muse, mutect2, varscan2
- IL24 | c.69G>A p.A23= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs756993638, COSV54321137; called by muse, mutect2, varscan2
- LHX9 | c.1014C>T p.D338= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV100435806; called by muse, mutect2, varscan2
- TVP23C | c.654G>T p.A218= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99846820; called by muse, mutect2, varscan2
- UBAP2 | c.1611G>T p.G537= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV100671258; called by muse, mutect2, varscan2
- UTP14C | c.630T>C p.S210= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV101584271; called by muse, mutect2
